Somatic mutation profile of tumor specimen TCGA-MT-A67D-01A (aliquot TCGA-MT-A67D-01A-31D-A30E-08) from TCGA case TCGA-MT-A67D, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Anterior floor of mouth; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 55.8 years (20,386 days).
Specimen TCGA-MT-A67D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 85ada4bd-3abc-4df1-8b76-24b6a31415b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MT-A67D-10A (Blood Derived Normal), aliquot TCGA-MT-A67D-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e4a990d4-3a8c-4ff0-a359-31187cc48e3d

The open-access MAF lists 111 somatic variants for this specimen: 82 protein-altering or splice-affecting, 26 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 26, Nonsense Mutation 5, Frame Shift Ins 3, Intron 2, Splice Site 1, In Frame Del 1, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA2 | c.2514dup p.Y839Ifs*42 | Frame Shift Ins (INS) | VAF 7/61 reads (11%) | catalogued as rs886040433; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- H3C3 | c.110A>T p.K37M | Missense Mutation (SNP) | VAF 20/98 reads (20%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.357); catalogued as COSV63550964, COSV63551270; called by muse, mutect2, varscan2
- KCTD7 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774026720, COSV51877044, COSV99299062; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCG2 | c.1881G>A p.W627* | Nonsense Mutation (SNP) | VAF 9/69 reads (13%) | catalogued as COSV99418991; called by muse, mutect2, varscan2
- ARHGAP17 | c.1619C>T p.P540L | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.205); catalogued as COSV99253237; called by muse, mutect2
- C3AR1 | c.122A>C p.N41T | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99368376; called by muse, mutect2, varscan2
- C5orf15 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as COSV99198308; called by muse, mutect2, varscan2
- CASP8 | c.938G>A p.C313Y (on ENST00000432109 / NM_033355.3; = p.C330Y on NM_001228.4) | Missense Mutation (SNP) | VAF 38/167 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as rs1225512894, COSV99630051; called by muse, mutect2, varscan2
- CDC14A | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.109); catalogued as COSV100324793; called by muse, mutect2
- CEP192 | c.2072C>T p.T691I | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as COSV100380980; called by mutect2, varscan2
- CLTCL1 | c.3751C>T p.R1251W | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as rs567114641, COSV99594835; called by muse, mutect2
- CNTNAP5 | c.610G>A p.V204M | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.041); catalogued as rs1422398172, COSV101443314; called by muse, mutect2, varscan2
- COL26A1 | c.757G>A p.G253S (on ENST00000313669 / NM_001278563.3; = p.G251S on NM_133457.4) | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs373938643; called by muse, mutect2, varscan2
- CYTH2 | c.907A>G p.I303V (on ENST00000427476; = p.I302V on NM_004228.7) | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.1); catalogued as COSV100287130; called by muse, mutect2, varscan2
- DGKZ | c.1558G>T p.G520* (on ENST00000454345 / NM_001105540.2; = p.G332* on NM_003646.4) | Nonsense Mutation (SNP) | VAF 14/89 reads (16%) | catalogued as COSV100551275; called by muse, mutect2, varscan2
- DNAH10 | c.12460G>A p.A4154T (on ENST00000409039; = p.A4093T on NM_207437.3) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.253); catalogued as COSV101292150; called by muse, mutect2
- DNAH5 | c.3676C>T p.R1226W | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); catalogued as rs146689446; called by muse, mutect2, varscan2
- DNAJA2 | c.292G>A p.G98S | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.066); catalogued as rs757412266, COSV100398832; called by muse, mutect2, varscan2
- DOCK10 | c.889C>T p.L297F | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.094); catalogued as COSV99288749; called by muse, mutect2
- EPHA5 | c.2494G>T p.A832S | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.962); catalogued as COSV99897936; called by muse, mutect2, varscan2
- FKBPL | c.632G>A p.R211K | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV100913554; called by muse, mutect2, varscan2
- FSIP1 | c.1676G>A p.S559N | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV100618030; called by muse, mutect2, varscan2
- FUT3 | c.344C>A p.S115Y | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs141188376, COSV99041625; called by muse, mutect2, varscan2
- FUZ | c.1132G>A p.V378M | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.103); catalogued as COSV100571092; called by muse, mutect2, varscan2
- GALK1 | c.781del p.E261Kfs*3 | Frame Shift Del (DEL) | VAF 14/87 reads (16%) | catalogued as COSV52324827; called by mutect2, pindel, varscan2
- GATA3 | c.851G>A p.C284Y | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100650926; called by muse, mutect2, varscan2
- GDF3 | c.788T>A p.L263H | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100325212, COSV100325339; called by muse, mutect2, varscan2
- GRK7 | c.224C>A p.A75D | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.018); catalogued as rs1416786611, COSV99379733; called by muse, mutect2, varscan2
- GTSE1 | c.270G>A p.W90* | Nonsense Mutation (SNP) | VAF 18/220 reads (8%) | catalogued as COSV101483199; called by muse, mutect2
- IKBKB | c.695A>G p.H232R | Missense Mutation (SNP) | VAF 21/211 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.864); catalogued as COSV100645652; called by muse, mutect2
- IQCE | c.464A>G p.K155R | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100383321; called by muse, mutect2, varscan2
- KCNH7 | c.28C>A p.P10T | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100035078; called by muse, mutect2, varscan2
- KIAA0895L | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs767927390, COSV51782786; called by muse, mutect2, varscan2
- KIF18B | c.1297G>A p.G433R (on ENST00000593135 / NM_001265577.2; = p.G445R on NM_001264573.2) | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.408); catalogued as COSV100191960; called by muse, mutect2, varscan2
- KIF23 | c.937C>T p.P313S | Missense Mutation (SNP) | VAF 37/204 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1567063656, COSV99532185; called by muse, mutect2, varscan2
- KMT2D | c.5005C>T p.P1669S | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.091); catalogued as COSV56468181; called by muse, mutect2, varscan2
- LDB3 | c.1505C>T p.P502L | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs528611881, COSV53948106; ClinVar: uncertain significance; called by muse, varscan2
- LENG9 | c.1324G>C p.E442Q | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.801); catalogued as COSV100002751; called by muse, mutect2, varscan2
- MAP3K5 | c.2567G>C p.R856T | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100752665; called by muse, mutect2, varscan2
- MAPK8 | c.194C>T p.T65I | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.82); PolyPhen probably damaging (0.987); catalogued as COSV100827398; called by muse, mutect2, varscan2
- MTF1 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.051); catalogued as COSV100888613; called by muse, mutect2, varscan2
- MUC5B | c.5801C>T p.P1934L | Missense Mutation (SNP) | VAF 39/193 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.137); catalogued as rs1485975906; called by muse, mutect2, varscan2
- NCOA7 | c.2001G>T p.M667I | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV99996833; called by muse, mutect2
- NOTCH1 | c.5294G>A p.G1765D | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs1446572888, COSV99486763; called by mutect2, varscan2
- NPR1 | c.1279A>C p.N427H | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.04); catalogued as COSV100903738; called by muse, mutect2, varscan2
- OR2T6 | c.128G>A p.G43E | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.196); catalogued as rs986051610, COSV100861506, COSV100861523; called by muse, mutect2
- PCCA | c.1321A>T p.I441F | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100886735; called by muse, mutect2, varscan2
- PCDHA4 | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100793296; called by muse, mutect2, varscan2
- PCED1B | c.251C>A p.S84Y | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV101423626; called by muse, mutect2, varscan2
- PHC2 | c.782C>T p.P261L | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99930906; called by muse, mutect2, varscan2
- PI4KB | c.1271G>A p.R424Q (on ENST00000368873 / NM_001369623.1; = p.R436Q on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as rs200350201, COSV99649508, COSV99649540; called by muse, mutect2, varscan2
- PIGK | c.819G>T p.Q273H | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); catalogued as COSV100769829; called by muse, mutect2
- PLCD1 | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs773011878, COSV100587429, COSV100587744; called by muse, varscan2
- PLD1 | c.2621C>A p.S874* | Nonsense Mutation (SNP) | VAF 6/70 reads (9%) | catalogued as COSV100577933; called by muse, mutect2
- PLD1 | c.1471G>A p.E491K | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.254); catalogued as COSV100577934; called by muse, mutect2, varscan2
- PPFIA4 | c.2494C>T p.P832S (on ENST00000447715; = p.P833S on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs560309517, COSV99690462; called by muse, mutect2, varscan2
- PRSS27 | c.278G>A p.R93K | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.301); catalogued as COSV100234509; called by muse, mutect2
- RALGPS2 | c.926C>T p.P309L | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV100243756; called by muse, mutect2, varscan2
- RELN | c.3337G>A p.G1113R | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100633204; called by muse, mutect2, varscan2
- RPE65 | c.1339-1G>T p.X447_splice | Splice Site (SNP) | VAF 4/39 reads (10%) | catalogued as COSV99253766; called by muse, mutect2, varscan2
- SERPINA1 | c.65C>T p.S22F | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.019); catalogued as COSV100872057; called by muse, mutect2
- SHOC2 | c.350C>A p.S117* | Nonsense Mutation (SNP) | VAF 8/102 reads (8%) | catalogued as COSV99510044, COSV99510191; called by muse, mutect2
- SLC5A3 | c.274C>T p.L92F | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as rs757471736, COSV100757832; called by muse, mutect2, varscan2
- SLCO1C1 | c.617C>T p.P206L | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56881599; called by muse, mutect2
- SPRED2 | c.845G>A p.G282D | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV100710148; called by muse, mutect2, varscan2
- TCF12 | c.1304T>C p.L435S | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as CM131562, COSV99977034; called by muse, mutect2, varscan2
- TMEM190 | c.268G>A p.G90S | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.172); catalogued as COSV52581893, COSV52581976; called by muse, mutect2, varscan2
- TRAPPC9 | c.1555G>A p.E519K | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.428); catalogued as COSV101227135; called by muse, mutect2, varscan2
- TRIM23 | c.737A>T p.D246V | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.151); catalogued as COSV99139925; called by muse, mutect2, varscan2
- TXLNA | c.332A>G p.E111G | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV101009828, COSV65314155; called by muse, mutect2, varscan2
- UBR4 | c.8233G>A p.G2745R | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.127); catalogued as COSV100920663; called by muse, mutect2, varscan2
- USP21 | c.307C>T p.P103S | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.01); catalogued as COSV99237304; called by muse, mutect2, varscan2
- WDCP | c.1786C>G p.Q596E | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV54592516; called by muse, mutect2
- WDR90 | c.3536G>A p.R1179Q | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs540761626, COSV99553100; called by muse, mutect2, varscan2
- ZC3HAV1L | c.599G>T p.G200V | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99312895; called by muse, mutect2, varscan2
- ZNF132 | c.2113C>A p.H705N | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV99571075; called by muse, mutect2, varscan2
- ZNF14 | c.872T>A p.L291H | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0.179); catalogued as COSV100694026; called by muse, mutect2, varscan2
- PHRF1 | c.2131_2136del p.I711_S712del (on ENST00000264555 / NM_001286581.2; = p.I710_S711del on NM_020901.4) | In Frame Del (DEL) | VAF 17/123 reads (14%) | called by mutect2, pindel, varscan2
- PRAMEF1 | c.891C>A p.N297K | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.423); called by muse, mutect2
- SLC12A2 | c.3144dup p.W1049Mfs*5 | Frame Shift Ins (INS) | VAF 23/134 reads (17%) | called by mutect2, pindel, varscan2
- SPDYE5 | c.744C>A p.F248L | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.27); called by mutect2, varscan2
- SVEP1 | c.9286dup p.I3096Nfs*23 | Frame Shift Ins (INS) | VAF 24/241 reads (10%) | called by mutect2, pindel
- ABCA12 | c.5295C>A p.G1765= (on ENST00000272895 / NM_173076.3; = p.G1447= on NM_015657.3) | Silent (SNP) | VAF 21/126 reads (17%) | catalogued as rs772205754, COSV99789343; called by muse, mutect2, varscan2
- ANKRD35 | c.1251T>C p.H417= | Silent (SNP) | VAF 12/101 reads (12%) | catalogued as rs373131719; called by muse, mutect2
- ARHGEF38 | c.171G>A p.R57= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as rs1284511380, COSV99486208; called by muse, mutect2, varscan2
- BRCA2 | c.264G>A p.L88= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as COSV101204109; called by muse, mutect2, varscan2
- CCT4 | c.648G>A p.G216= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as rs771377430, COSV101075148; called by muse, mutect2, varscan2
- CLUH | c.1998G>A p.E666= (on ENST00000435359; = p.E704= on NM_015229.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/68 reads (29%) | catalogued as COSV101425702; called by muse, mutect2, varscan2
- CNTNAP4 | c.2616C>T p.N872= | Silent (SNP) | VAF 22/174 reads (13%) | catalogued as rs750280867, COSV56705609, COSV56708519; called by muse, mutect2, varscan2
- CPNE7 | c.1719G>A p.A573= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as rs754974067, COSV52011361; called by muse, mutect2, varscan2
- DNAH1 | c.6876C>T p.F2292= | Silent (SNP) | VAF 12/100 reads (12%) | catalogued as COSV101325387; called by muse, mutect2
- FAT1 | c.8577C>G p.S2859= | Silent (SNP) | VAF 22/92 reads (24%) | catalogued as COSV101499249; called by muse, mutect2, varscan2
- INCENP | c.978C>T p.A326= | Silent (SNP) | VAF 17/125 reads (14%) | catalogued as rs1456078302, COSV99610871; called by muse, mutect2, varscan2
- LRP1B | c.8193A>G p.K2731= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as rs1411982670, COSV101255035; called by muse, mutect2, varscan2
- NTNG2 | c.675C>T p.P225= | Silent (SNP) | VAF 22/152 reads (14%) | catalogued as rs1176165518, COSV62366148; called by muse, mutect2, varscan2
- PCDHB11 | c.702C>T p.D234= | Silent (SNP) | VAF 28/146 reads (19%) | catalogued as rs781795665, COSV99504054; called by muse, mutect2, varscan2
- PRR27 | c.330G>A p.P110= | Silent (SNP) | VAF 51/280 reads (18%) | catalogued as rs759437234, COSV60640700; called by muse, mutect2, varscan2
- PTPRM | c.951G>A p.E317= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as rs1309037397, COSV59883627; called by muse, mutect2, varscan2
- SCNN1B | c.474C>T p.P158= | Silent (SNP) | VAF 15/161 reads (9%) | called by muse, mutect2
- SEMA5A | c.945G>A p.A315= | Silent (SNP) | VAF 17/148 reads (11%) | catalogued as rs755886549, COSV101227666; called by muse, mutect2, varscan2
- SLC27A4 | c.309C>T p.T103= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as COSV100056576; called by muse, mutect2, varscan2
- SPTBN1 | c.2826A>G p.E942= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV100442257; called by muse, mutect2, varscan2
- TNNT3 | c.771G>A p.G257= (on ENST00000397301 / NM_001367846.1; = p.G246= on NM_006757.4) | Silent (SNP) | VAF 30/115 reads (26%) | catalogued as COSV99548123; called by muse, mutect2, varscan2
- TUT1 | c.687C>T p.P229= | Silent (SNP) | VAF 24/142 reads (17%) | catalogued as rs766381068, COSV99545210; called by muse, mutect2, varscan2
- WDR90 | c.4935G>A p.G1645= | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as rs1399855784, COSV99553101; called by muse, mutect2, varscan2
- ZBTB32 | c.99C>T p.I33= | Silent (SNP) | VAF 13/136 reads (10%) | catalogued as COSV99385967; called by muse, mutect2, varscan2
- ZDHHC6 | c.858A>G p.G286= | Silent (SNP) | VAF 4/76 reads (5%) | catalogued as COSV101024381; called by muse, mutect2
- ZNF264 | c.168T>A p.P56= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as COSV99567186; called by muse, mutect2
- DDX39B | c.616+107A>G | Intron (SNP) | VAF 8/71 reads (11%) | catalogued as rs913763708, COSV100795189, COSV100795275; called by muse, mutect2, varscan2
- NEDD8 | chr14:24213504 G>A | 3'Flank (SNP) | VAF 6/59 reads (10%) | catalogued as COSV99164611; called by muse, mutect2
- TSPEAR | c.83-33075C>T | Intron (SNP) | VAF 32/248 reads (13%) | called by muse, mutect2, varscan2
